MMRF case MMRF_1356 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c86f72e4-b4e6-4c77-82e5-0898013e950a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.4 years (25,706 days); ISS stage: I; Days to last known disease status: 1,501 days (4.1 years); Days to last follow up: 1,501 days (4.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 464 days (1.3 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 552 days (1.5 years); Days to treatment end: 552 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 659 days (1.8 years); Days to treatment end: 1,002 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,018 days (2.8 years); Days to treatment end: 1,298 days (3.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,424 days (3.9 years); Days to treatment end: 1,501 days (4.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 86.6 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.338 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 11.7 mmol/L.
- Day 134 (ECOG 2): Hemoglobin 6.08 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 243 ×10⁹/L.
- Day 176 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.3 mg/dL; Immunoglobulin G 3.47 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Glucose 11.6 mmol/L.
- Day 260 (ECOG 1): Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.3 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 11.1 mmol/L.
- Day 464: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 70 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.207 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 7.76 mmol/L.
- Day 568 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.8 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.439 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 11.8 mmol/L.
- Day 649 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.223 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.9 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 3.69 mmol/L.
- Day 701 (ECOG 1): Hemoglobin 8.43 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.21 mmol/L.
- Day 829 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.19 mg/dL; Immunoglobulin G 9.09 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 10.3 mmol/L.
- Day 911 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.5 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 10.2 mmol/L.
- Day 1,002: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.5 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.71 mmol/L.
- Day 1,045: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.7 mg/dL; Immunoglobulin G 8.53 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 18.8 mmol/L.
- Day 1,101 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 20.5 mmol/L.
- Day 1,186: Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 13 mmol/L.
- Day 1,298: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.5 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 5.4 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 45 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 9.68 mmol/L.
- Day 1,410 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 107 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.5 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 166 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 8.31 mmol/L.
- Day 1,501: M Protein 0.8 g/dL; Immunoglobulin G 8.87 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 257 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 7.81 mmol/L.

Other clinical attributes
- Day -27: Weight: 96 kg; Height: 171 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1356_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1356_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
